TCGA case TCGA-DX-AB2Q — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Fibromatous Neoplasms; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e2272de4-02b8-4a94-b8ee-c7454996a2da

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Country of residence at enrollment: United States; Age at index: 65 years; Vital status: Alive.

Diagnoses (3)
1. Malignant fibrous histiocytoma (the primary disease): ICD-O-3 morphology code: 8830/3; ICD-10 code: C49.2; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of lower limb and hip; Classification of tumor: primary; Age at diagnosis: 65.0 years (23,748 days); Year of diagnosis: 2009; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Sites of involvement: Groin; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 4; Tumor length measurement: 9; Tumor width measurement: 8.
   Pathology details: Consistent pathology review: Yes; Margin status: Uninvolved; Necrosis percent: 5; Necrosis present: Yes; Tumor depth descriptor: Deep.
2. Metastasis of diagnosis 1 (Malignant fibrous histiocytoma), site: Lymph nodes of inguinal region or leg. Age at diagnosis: 66.4 years (24,238 days); Days to diagnosis: 490 days (1.3 years); Prior treatment: Yes; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 6.8; Tumor length measurement: 9.2; Tumor width measurement: 8.5.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease.
3. Metastasis of diagnosis 1 (Malignant fibrous histiocytoma), site: Pelvis, NOS. Age at diagnosis: 66.4 years (24,238 days); Days to diagnosis: 490 days (1.3 years); Prior treatment: Yes; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 6.8; Tumor length measurement: 9.2; Tumor width measurement: 8.5.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease.

Follow-up (4 entries)
- Day 490 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Pelvis, NOS; Days to progression: 490 days (1.3 years).
- Day 490 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lymph nodes of inguinal region or leg; Days to progression: 490 days (1.3 years).
- Days to follow up: 1,496 days (4.1 years); Disease response: Tumor Free.
- Days to follow up: 2,030 days (5.6 years); Disease response: Tumor Free.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DX-AB2Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 720 mg.
  Slide TCGA-DX-AB2Q-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DX-AB2Q-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DX-AB2Q-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free.
- Primary pathology: Histologic diagnosis: Pleomorphic 'MFH' / Undifferentiated pleomorphic sarcoma; Margin status: Negative; Tumor total necrosis: <10% (focal necrosis); Disease multifocal indicator: No; Locoregional recurrence indicator: No; Metastatic disease confirmed: Yes; Metastasis site: Groin.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Lower Extremity - Lower leg/calf.
- Primary pathology, Tumor sizes, Tumor size: Lesion pathologic length: 9; Lesion pathologic width: 8; Lesion pathologic depth: 4.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Response.
- Radiation treatment: Days from index date to radiation therapy started: 95; Days from index date to radiation therapy ended: 152; Radiation therapy type: External; Radiation total dose: 6300; Radiation adjuvant units: cGy; Radiation adjuvant fractions total: 35; Radiation therapy site: Primary Tumor Field; Radiation therapy ongoing indicator: No; Treatment best response: Complete Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,030 days; disease-specific survival: no event (censored), 2,030 days; disease-free interval: event (new tumor event after initially disease-free), 490 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 490 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DX-AB2Q-01A-11D-A38Y-01): tumor purity 0.6, ploidy 4.56, whole-genome doublings 2.
